Gene-level copy-number profile of tumor specimen TCGA-38-4632-01A from TCGA case TCGA-38-4632, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.2 years (15,418 days).
Specimen TCGA-38-4632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f2cf7154-9187-41fd-a22c-d70145e59200.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4632-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f31d5149-715f-4fc6-91ee-92334ef2dec5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,351; copy number 3: 17,689; copy number 4: 12,844; copy number 5: 7,463; copy number 6: 6,960; copy number 7: 2,011; copy number 8: 602; copy number 9: 1,571; copy number 10: 254; copy number 11: 1; copy number 16: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-38-4632-01A-01D-1752-01): tumor purity 0.37, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,507 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr6:146,802,359–147,204,614, 5 genes, copy number 10 (within-gene range 3–10): KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1.
- chr7:70,972–54,812,727, 934 genes, copy number 7 (broad region; genes not listed).
- chr7:81,946,444–82,443,777, 1 gene, copy number 7 (within-gene range 5–7): CACNA2D1.
- chr7:82,589,848–82,590,691, 1 gene, copy number 7: MTHFD2P5.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr11:67,006,778–71,639,769, 163 genes, copy number 7 (broad region; genes not listed).
- chr11:77,313,606–78,079,865, 25 genes, copy number 8: TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2.
- chr11:85,694,224–87,025,777, 33 genes, copy number 7 (within-gene range 3–7): SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:87,094,734–87,121,596, 2 genes, copy number 7: XIAPP2, AP002967.1.
- chr11:87,847,259–88,428,176, 13 genes, copy number 9: AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1.
- chr11:90,223,153–90,915,052, 5 genes, copy number 8 (within-gene range 4–8): AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1.
- chr11:92,352,096–92,896,470, 1 gene, copy number 8 (within-gene range 4–8): FAT3.
- chr11:92,498,152–94,181,968, 50 genes, copy number 8: RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16, PANX1.
- chr11:94,188,449–94,188,997, 1 gene, copy number 8: ARPC3P3.
- chr11:94,874,052–95,748,715, 20 genes, copy number 10 (within-gene range 4–10): AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2.
- chr11:105,609,994–106,101,975, 9 genes, copy number 7 (within-gene range 4–7): GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1.
- chr11:107,591,091–107,666,779, 1 gene, copy number 8 (within-gene range 4–8): ELMOD1.
- chr11:107,642,887–107,963,482, 6 genes, copy number 8 (within-gene range 4–8): AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A.
- chr11:111,245,726–112,120,016, 44 genes, copy number 10 (within-gene range 3–10): C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1, AP000907.2, DLAT, PPIHP1, RNU6-893P, AP000907.3, PIH1D2, NKAPD1, TIMM8B, SDHD.
- chr11:115,169,218–120,319,945, 172 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:121,238,304–121,633,763, 7 genes, copy number 8 (within-gene range 3–8): AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr11:124,093,592–124,320,288, 14 genes, copy number 9: OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1, OR8D1, OR8D2.
- chr14:36,320,753–36,656,163, 1 gene, copy number 8 (within-gene range 6–8): AL132857.1.
- chr14:36,405,214–38,371,338, 33 genes, copy number 8: RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr18:1,883,524–2,489,426, 1 gene, copy number 8 (within-gene range 4–8): AP005230.1.
- chr18:2,506,628–3,330,984, 30 genes, copy number 8: AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1.
- chr19:33,621,953–45,092,635, 598 genes, copy number 7–16 (within-gene range 6–16) (broad region; genes not listed).
- chr20:22,343,693–22,343,930, 1 gene, copy number 11: AL121912.1.
- chr20:59,395,496–59,847,711, 6 genes, copy number 9 (within-gene range 4–9): AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1.
- chr21:36,430,360–39,929,397, 86 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
